Somatic mutation profile of tumor specimen TCGA-EJ-A7NM-01A (aliquot TCGA-EJ-A7NM-01A-21D-A33T-08) from TCGA case TCGA-EJ-A7NM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.6 years (23,603 days).
Specimen TCGA-EJ-A7NM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 210ce5fe-a784-4f46-950d-5b501b5e2f6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A7NM-10A (Blood Derived Normal), aliquot TCGA-EJ-A7NM-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bb3a779-2753-4c00-8e10-244844ef503e

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Nonsense Mutation 4, RNA 1, Intron 1, In Frame Del 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD8 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99395555; called by muse, mutect2, varscan2
- AC109583.1 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.862); catalogued as COSV100167969; called by muse, mutect2, varscan2
- ACTA1 | c.15C>A p.D5E | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100796794, COSV64202815; called by muse, mutect2, varscan2
- ADAMTS13 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs138770906; called by muse, mutect2
- ADCY2 | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100603445; called by muse, mutect2, varscan2
- AEBP1 | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1170503082, COSV56256231; called by muse, mutect2, varscan2
- ARMH3 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs763192348, COSV64234193; called by muse, mutect2, varscan2
- BCDIN3D | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs192965804, COSV100445569; called by muse, mutect2
- BMERB1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs201932527; called by muse, mutect2, varscan2
- CEBPZ | c.1158A>C p.Q386H | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV99135770; called by muse, mutect2, varscan2
- CEP170 | c.2433A>T p.K811N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100317770; called by muse, mutect2, varscan2
- ERMN | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV101263066, COSV68075453; called by muse, mutect2, varscan2
- FAT2 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); catalogued as rs370670557; called by muse, mutect2, varscan2
- GGT5 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763495821, COSV54069750; called by muse, mutect2, varscan2
- H2AZ1 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as COSV99597591; called by muse, mutect2, varscan2
- HOXC11 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs945809469, COSV99678515; called by muse, mutect2
- IFT88 | c.1918A>G p.I640V (on ENST00000319980 / NM_001318493.2; = p.I631V on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.42); catalogued as COSV100179887; called by muse, mutect2, varscan2
- KCND3 | c.106A>T p.K36* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100138370; called by muse, mutect2
- LEXM | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs201438425, COSV100827733; called by muse, varscan2
- LRRN4 | c.842A>G p.Q281R | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV101125518; called by muse, mutect2, varscan2
- MEGF10 | c.3139G>A p.G1047S | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs1403664666, COSV99175555; called by muse, mutect2, varscan2
- METTL21C | c.489T>A p.H163Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99940140; called by muse, mutect2, varscan2
- MIS18A | c.120C>G p.S40R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV99267135; called by muse, mutect2, varscan2
- MMP11 | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV99303361; called by muse, mutect2, varscan2
- MTMR2 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as rs776757548, COSV100656832; called by muse, mutect2, varscan2
- OMP | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs782075647, COSV53685717, COSV99581949; called by muse, mutect2
- PSG7 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 111/386 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.091); catalogued as COSV101343301, COSV101343331; called by muse, mutect2, varscan2
- PYHIN1 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 18/120 reads (15%) | PolyPhen benign (0.249); catalogued as COSV100932638, COSV100932685; called by muse, mutect2, varscan2
- REXO5 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | catalogued as rs1433011514, COSV99759464; called by muse, mutect2, varscan2
- RFX7 | c.634C>T p.R212W (on ENST00000559447 / NM_001368074.1; = p.R309W on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753217039, COSV100428099; called by muse, mutect2, varscan2
- SPOCD1 | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV99930328; called by muse, mutect2, varscan2
- TAF1L | c.3145C>T p.R1049C | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535964605, COSV54258565; called by muse, mutect2, varscan2
- UGT2A3 | c.513A>T p.R171S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV99280190; called by muse, mutect2, varscan2
- WDR3 | c.931A>G p.K311E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100832367; called by muse, mutect2, varscan2
- XPO4 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV55015013; called by muse, mutect2, varscan2
- ZBTB24 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV100018725; called by muse, mutect2, varscan2
- ZFYVE1 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100607096; called by muse, mutect2, varscan2
- EQTN | c.408_410del p.M137del | In Frame Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- FOXA1 | c.245_258del p.V82Gfs*140 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel
- ADORA3 | c.75C>T p.C25= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs368279686; called by muse, varscan2
- ASB8 | c.801C>T p.L267= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100402710; called by muse, mutect2, varscan2
- ATP1A4 | c.858G>A p.A286= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as rs369914363; called by muse, mutect2, varscan2
- CCDC114 | c.1254G>A p.L418= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100197034; called by muse, mutect2, varscan2
- CCN2 | c.324G>C p.T108= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100915359, COSV100915367; called by muse, mutect2, varscan2
- FGA | c.702C>T p.P234= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs774638560, COSV57395360; called by muse, mutect2, varscan2
- ITGB2 | c.2031G>A p.S677= (on ENST00000302347; = p.S653= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs545524615, COSV100186117; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC5AC | c.15537G>A p.T5179= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs563195430, COSV100611574; called by muse, mutect2, varscan2
- SLC23A1 | c.1050C>A p.P350= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV100812096; called by muse, mutect2, varscan2
- TTN | c.42627C>T p.F14209= (on ENST00000591111; = p.F6785= on NM_003319.4) | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs113350914, COSV100601474; called by muse, mutect2, varscan2
- ZNF462 | c.6327C>G p.A2109= | Silent (SNP) | VAF 91/286 reads (32%) | catalogued as COSV99473187; called by muse, mutect2, varscan2
- ZPLD1 | c.192G>A p.S64= (on ENST00000466937 / NM_001329788.1; = p.S80= on NM_175056.2) | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs757680849, COSV100083534; called by muse, mutect2, varscan2
- PLEC | c.524-3779G>C | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100518574; called by muse, mutect2, varscan2
- SSPOP | n.11096G>T | RNA (SNP) | VAF 8/18 reads (44%) | catalogued as rs370804598, COSV100947986; called by muse, varscan2
